Gene-level copy-number profile of tumor specimen TCGA-ER-A2NG-06A from TCGA case TCGA-ER-A2NG, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 45.1 years (16,470 days).
Specimen TCGA-ER-A2NG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.5c7a41c6-7bc8-4bc6-8180-43fa4342f00f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A2NG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ff83c8e3-996e-4fae-aa3e-6b775e19ed14

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 12,706; copy number 3: 8,324; copy number 4: 32,954; copy number 5: 1,381; copy number 6: 747; copy number 7: 2,430; copy number 8: 113; copy number 9: 837; copy number 11: 158; copy number 12: 130; copy number 13: 1; copy number 28: 28; copy number 37: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A2NG-06A-11D-A194-01): tumor purity 0.48, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,159 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,930,040–155,234,325, 148 genes, copy number 11 (broad region; genes not listed).
- chr1:196,225,779–197,009,678, 10 genes, copy number 11 (within-gene range 6–11): KCNT2, MIR4735, CFH, CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5.
- chr3:66,997,168–77,649,964, 130 genes, copy number 12 (within-gene range 7–12) (broad region; genes not listed).
- chr4:41,303,237–43,492,543, 34 genes, copy number 13–37: Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1, AC096734.2, AC096734.1, RN7SKP82, GRXCR1, AC111198.1, AC097451.1, AC098590.2, LINC02383.
- chr19:28,316,705–47,581,321, 837 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
